Somatic mutation profile of tumor specimen TARGET-10-PAPDYE-09A (aliquot TARGET-10-PAPDYE-09A-01D) from TARGET case TARGET-10-PAPDYE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,408 days).
Specimen TARGET-10-PAPDYE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cb60d5e-cc06-4a59-b90a-84f57c891cd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDYE-10A (Blood Derived Normal), aliquot TARGET-10-PAPDYE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a7a718-5fcf-4bb7-b3a7-4566a68915c7

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 41/199 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA2D3 | c.437del p.L146Wfs*9 | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | catalogued as COSV55589697; called by mutect2, pindel, varscan2
- GARNL3 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746643506; called by muse, mutect2, varscan2
- PCDHA12 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV56513273; called by muse, mutect2, varscan2
- VEGFC | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1306316719, COSV54595552; called by muse, mutect2, varscan2
- YAP1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs867350713, COSV56776236; called by muse, mutect2, varscan2
- SCG5 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2
- GTPBP4 | c.1086G>A p.L362= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- ZFPM2 | c.1170A>G p.K390= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV65875631; called by muse, mutect2, varscan2
- TXNRD2 | c.949+248G>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
